Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7789, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7789-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a serum PSA value of 14.9 ng/mL. The patient had a biopsy on [REDACTED] his biopsy revealed small foci of prostatic adenocarcinoma. Gleason score 3+3 = 6 involving the left lobe and right prostate lobes (< 1% of the cores). He also had prior biopsies [REDACTED] showed focal high-grade prostatic intraepithelial neoplasia.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymphadenectomy.

FINAL DIAGNOSIS:

PART1: LYMPH NODES, RIGHT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN SEVEN VARIABLY HYPERPLASTIC LYMPH NODES (0/7).

PART2: LYMPH NODES, LEFT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN SEVEN VARIABLY HYPERPLASTIC LYMPH NODES (0/7).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY –

A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, MULTIFOCAL:

- a. DOMINANT NODULE LOCATED IN THE RIGHT AND LEFT MID – BASE PROSTATE (WITH A PROMINENT ANTERIOR COMPONENT) IS A PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4+3=7, WITH A PROMINENT TERTIARY GLEASON PATTERN 5 COMPONENT. GLEASON PATTERNS 4/5 COMPONENTS COMPRISE APPROXIMATELY 70% OF THE DOMINANT TUMOR VOLUME (See comment).
- b. ADDITIONAL SEPARATE SMALL PROSTATIC ADENOCARCINOMAS RANGING FROM GLEASON SCORE 3+3=6 TO 4+3=7.

B. CARCINOMA (DOMINANT NODULE) HAS A GREATEST NODULAR DIAMETER OF 1.9 CM IN ONE HISTOLOGIC SECTION (SLIDE 3FF).

C. CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.

D. ESTABLISHED EXTRACAPSULAR EXTENSION IS PRESENT IN THE RIGHT ANTERIOR BASE (SLIDE 3P) AND FOCAL EXTRACAPSULAR EXTENSION IS PRESENT IN THE LEFT ANTERIOR BASE (SLIDE 3S).

E. RARE PERINEURAL INVASION IS IDENTIFIED (SLIDE 3P).

F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.

G. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE BENIGN.

H. ALL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.

I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.

J. PATHOLOGIC TNM STAGE: pT3a N0 MX (See synoptic).

K. HISTOLOGIC GRADE G3-4.

L. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

COMMENT:

Part 3: This patient has undergone multiple prior prostate needle biopsies, with the most recent biopsy [REDACTED] showing only small bilateral foci of prostatic adenocarcinoma, Gleason score 3+3=6. The higher grade components of the dominant nodule were not sampled in this prostate needle biopsy.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 14.9
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	70%
WEIGHT OF PROSTATE:	41.20gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	14
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4. Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file dc342948-df45-4e24-a7da-783a9e4db01f (TCGA-EJ-7789.7483212D-F96C-4AFD-B817-74517B54DE53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).